FM case AD3431 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/098166de-d540-40a7-8703-8728f94a7653

Female, 66.6 years: Duct adenocarcinoma, NOS (ICD-O-3 8500/3) of the pancreas; primary biopsied or resected from the pancreas. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
